TCGA case TCGA-59-2372 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5d8abed4-62b3-4e17-a8ce-9f6028e97103

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Dead; Days to death: 1,363 days (3.7 years).

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Year of diagnosis: 2005; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G2; Prior treatment: No; Residual disease: R0.
   Pathology details: Lymphatic invasion present: No; Residual tumor measurement: No macroscopic disease; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Number of cycles: 4.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Number of cycles: 4.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,363.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-59-2372-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-59-2372-01A-01-BS1: Section location: Bottom; Percent tumor cells: 98; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-59-2372-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-59-2372-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.

GDC annotations on this case (curator notes; quoted as recorded):
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-59-2372-01A-01R-1048-01: Pairwise comparisons of expression results between platforms HT_HG-U133A and AgilentG4502A_07 suggests that results from this aliquot were from a different patient and therefore these data have been removed.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,363 days; disease-specific survival: event status not recorded, 1,363 days; progression-free interval: no event (censored), 1,363 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-59-2372-01A-01D-1043-01): tumor purity 0.97, ploidy 3.24, whole-genome doublings 1.
